Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5008, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5008-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Right renal mass.

TCGA-BP-5008

Specimens Submitted:

1: KIDNEY, RIGHT; NEPHRECTOMY

DIAGNOSIS:

1. KIDNEY, RIGHT; NEPHRECTOMY:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 2.5 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild chronic interstitial inflammation and fibrosis

Adrenal Gland:

Not Identified

Lymph Nodes:

Not Identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received in fresh state, labeled as "right kidney", and it consists of a right kidney measuring 8.5 x 6.1 X 4.0 cm and perirenal fat weighing in total 298 g. A segment of ureter measuring 7.5 cm in length and 0.6 cm in circumference is attached. Adrenal gland is not identified. The specimen is previously sectioned multiple times for TPS. The specimen surface is inked. There is a 2.5 x 2.0 x 1.6 cm completely encapsulated severely hemorrhagic mass in the anterior mid portion of the renal cortex. The tumor is medially bosselated, but renal capsule or adjacent sinus fat is grossly uninvolved. No vascular tumor thrombi are grossly identified. Background renal parenchyma is grossly unremarkable. Mucosa of pelvis and ureter appears grossly unremarkable. There is no lymph node identified in the perirenal fat. The specimen is photographed. TPS is taken.

Summary of sections:

UM -- ureteral margin

VM -- vascular margin

T -- tumor with capsule and sinus fat, entirely submitted

P -- pelvic mucosa

K -- background renal parenchyma

Summary of Sections:

Part 1: KIDNEY, RIGHT; NEPHRECTOMY

Block	Sect. Site	PCs
1	k	1
1	p	1
5	t	5
1	um	1
1	vm	1

Source: NCI Genomic Data Commons file 869afd1e-fa02-402a-a2db-3bb9bd47a737 (TCGA-BP-5008.D5FF5D2D-9935-4E27-82F9-91D000CC6252.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).